Somatic mutation profile of tumor specimen TCGA-CR-7404-01A (aliquot TCGA-CR-7404-01A-11D-2129-08) from TCGA case TCGA-CR-7404, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G2; Age at diagnosis: 53.5 years (19,532 days).
Specimen TCGA-CR-7404-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56269774-d821-420c-8c43-a22111babcc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7404-10A (Blood Derived Normal), aliquot TCGA-CR-7404-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b382070-4c04-4a23-8bca-d9ee36c53d47

The open-access MAF lists 126 somatic variants for this specimen: 90 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 32, Nonsense Mutation 7, Frame Shift Del 2, RNA 2, Splice Site 1, In Frame Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABHD16A | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.215); catalogued as rs1271413764, COSV65451551; called by muse, mutect2, varscan2
- ACSBG1 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99357814; called by muse, mutect2, varscan2
- AIFM2 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs763989866, COSV100325832; called by muse, mutect2, varscan2
- ALB | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99892180; called by muse, mutect2, varscan2
- ARHGAP19 | c.66C>G p.I22M | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as rs1187537755, COSV100363350, COSV57396701; called by muse, mutect2, varscan2
- ARL8B | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.276); catalogued as COSV99848841; called by muse, mutect2
- ATP13A4 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs763560145, COSV55068649; called by muse, mutect2
- ATXN2L | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs772610770, COSV100295231; called by muse, mutect2, varscan2
- BCL11A | c.1633G>A p.E545K (on ENST00000335712 / NM_001365609.1; = p.E579K on NM_018014.4) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.059); catalogued as COSV59639329; called by muse, mutect2, varscan2
- BRCA1 | c.2446C>T p.H816Y | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as COSV100525149; called by muse, mutect2
- CFAP53 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV101275039; called by muse, mutect2, varscan2
- CHGA | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.399); catalogued as COSV99381309; called by muse, mutect2
- CMKLR1 | c.730G>A p.V244M (on ENST00000312143 / NM_001142344.2; = p.V242M on NM_004072.3) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs761623535, COSV56436189; called by mutect2, varscan2
- CNST | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 17/105 reads (16%) | catalogued as COSV100830117; called by muse, mutect2, varscan2
- CSNK2A1 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 5/73 reads (7%) | catalogued as COSV53935771; called by muse, mutect2
- CXorf66 | c.350A>T p.D117V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100983948; called by muse, mutect2, varscan2
- CXorf66 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100983826, COSV100983949; called by muse, mutect2, varscan2
- DDX51 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV57961067; called by muse, mutect2, varscan2
- ELMO2 | c.1593G>C p.E531D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs757057713, COSV99282061; called by muse, mutect2, varscan2
- EPS8 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as rs1218112266, COSV99843719; called by muse, mutect2
- FRY | c.3035C>G p.A1012G | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as COSV100969948; called by muse, mutect2, varscan2
- GPRIN3 | c.232A>G p.M78V | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV100311025; called by muse, mutect2, varscan2
- GSE1 | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs984691309, COSV53676790, COSV99497247; called by muse, mutect2, varscan2
- GTPBP4 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs760507044, COSV62552706; called by mutect2, varscan2
- GUCY2F | c.1548C>G p.I516M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99485694; called by muse, mutect2, varscan2
- HFM1 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV99646872; called by muse, mutect2, varscan2
- HOXA1 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs751378994, COSV99761419; called by muse, mutect2, varscan2
- KCNK13 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs749400256, COSV56413137; called by muse, mutect2, varscan2
- KIDINS220 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99876513; called by muse, mutect2, varscan2
- KRTAP5-8 | c.145A>C p.S49R | Missense Mutation (SNP) | VAF 16/393 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV101273166; called by muse, mutect2
- LAMA4 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV100039513; called by muse, mutect2, varscan2
- LIPT1 | c.1084T>C p.W362R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV100399560; called by muse, mutect2, varscan2
- LMNTD2 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99530880; called by muse, mutect2, varscan2
- LMNTD2 | c.372G>C p.L124F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99530771; called by muse, mutect2, varscan2
- MARCO | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100503603, COSV59052677; called by muse, mutect2
- MIER2 | c.422C>A p.S141* | Nonsense Mutation (SNP) | VAF 12/264 reads (5%) | catalogued as COSV99316774; called by muse, mutect2
- MUC3A | c.7532C>G p.S2511C | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious, low confidence (0); catalogued as rs541628829, COSV100114521, COSV100115421; called by muse, mutect2, varscan2
- MYO15A | c.3358C>T p.R1120C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as rs375451997, COSV52760947; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYT1 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754846354, COSV100115514; called by muse, mutect2, varscan2
- NCF2 | c.1371G>C p.K457N | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV62315244; called by muse, mutect2
- NLRP12 | c.930G>T p.W310C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100145940, COSV60752478; called by muse, mutect2
- NOLC1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs750484400, COSV53383937; called by muse, mutect2, varscan2
- NUP210L | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.388); catalogued as COSV99669166; called by muse, mutect2
- OLFM3 | c.523G>C p.E175Q (on ENST00000338858 / NM_001288821.1; = p.E155Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.076); catalogued as COSV100130118, COSV58804696; called by muse, mutect2, varscan2
- OR51A2 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100985098; called by muse, mutect2
- OR51A2 | c.504G>C p.L168F | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV100985099; called by muse, mutect2, varscan2
- PCDH19 | c.2555C>G p.S852C (on ENST00000373034 / NM_001184880.2; = p.S805C on NM_020766.3) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV99720824; called by muse, mutect2
- PDK1 | c.532C>G p.Q178E | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV99961492; called by muse, mutect2
- PEG3 | c.139C>G p.Q47E | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750185882, COSV55634494, COSV99690510; called by muse, mutect2, varscan2
- PER1 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.598); catalogued as rs568837329, COSV100424866, COSV57920643; called by muse, varscan2
- PKNOX1 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 20/116 reads (17%) | catalogued as COSV99373137; called by muse, mutect2, varscan2
- PLD1 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 19/277 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100578942, COSV60574137; called by muse, mutect2
- PLXNB3 | c.5374G>A p.D1792N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737951; called by muse, mutect2, varscan2
- PREX1 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV64258117; called by muse, mutect2
- PRKAA1 | c.76C>A p.H26N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.09); catalogued as COSV99713437; called by mutect2, varscan2
- PTGER2 | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99817777; called by muse, mutect2, varscan2
- PTPRT | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1463467204, COSV100630677; called by muse, mutect2, varscan2
- QTRT2 | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV55561360, COSV99847050; called by muse, mutect2, varscan2
- REG1A | c.277A>T p.T93S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.316); catalogued as COSV52068123, COSV99286992; called by muse, mutect2, varscan2
- REG3G | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.374); catalogued as rs758489969, COSV55451494, COSV55451699, COSV99709734; called by muse, mutect2, varscan2
- SEZ6 | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs370021808; called by muse, mutect2, varscan2
- SLC4A11 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs1198138429, CD160132, COSV66260588; called by muse, mutect2, varscan2
- SLC8A1 | c.1441G>C p.D481H | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100247488, COSV60498667; called by muse, mutect2
- SLITRK4 | c.2102G>T p.G701V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.36); catalogued as COSV100567533; called by muse, mutect2, varscan2
- SPHKAP | c.2929C>T p.R977* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV100764549; called by muse, mutect2, varscan2
- STAT5A | c.1539G>A p.M513I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV100604846; called by muse, mutect2, varscan2
- SYNE2 | c.20443G>A p.E6815K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs146398606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TFDP1 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs760650590, COSV100946033; called by muse, mutect2, varscan2
- TMC5 | c.2903C>T p.S968L (on ENST00000396229 / NM_001105248.1; = p.S722L on NM_024780.5) | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs369268664; called by muse, mutect2, varscan2
- TNXB | c.10730T>A p.L3577H (on ENST00000647633; = p.L3330H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100926669; called by muse, mutect2, varscan2
- TNXB | c.10178C>T p.T3393M (on ENST00000647633; = p.T3146M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770332215, COSV100926670; called by muse, mutect2
- TPCN2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417355898, COSV99593979; called by muse, mutect2, varscan2
- TRPS1 | c.3634G>A p.E1212K (on ENST00000220888 / NM_001330599.2; = p.E1225K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99629255; called by muse, mutect2, varscan2
- TRPV6 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.828); catalogued as rs762397125, COSV63891740; called by muse, mutect2, varscan2
- TTC39B | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs963952739, COSV99896204; called by muse, mutect2, varscan2
- TTN | c.90043C>G p.L30015V (on ENST00000591111; = p.L22591V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | PolyPhen probably damaging (0.996); catalogued as rs748010504, COSV100631073; called by muse, mutect2, varscan2
- TTN | c.89771C>G p.S29924C (on ENST00000591111; = p.S22500C on NM_003319.4) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | PolyPhen probably damaging (0.935); catalogued as COSV100631075; called by muse, mutect2, varscan2
- TTN | c.21980G>A p.R7327Q (on ENST00000591111; = p.R6400Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | PolyPhen benign (0.254); catalogued as rs766675017, COSV60078936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UCK2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.932); catalogued as COSV100903053; called by muse, mutect2, varscan2
- XCL1 | c.146C>G p.T49S | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV100892218; called by muse, mutect2, varscan2
- ZBTB38 | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776417885, COSV100376017; called by muse, mutect2, varscan2
- ZNF827 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101061769, COSV65229017; called by muse, mutect2, varscan2
- MED12L | c.3530_3559+4del p.X1177_splice | Splice Site (DEL) | VAF 12/112 reads (11%) | called by mutect2, pindel
- MKRN3 | c.777_779del p.M259_Y260delinsI | In Frame Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- NIPBL | c.8342_8352del p.A2781Dfs*2 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- OR4D6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2
- RGS17 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.114); called by muse, mutect2
- SLC4A11 | c.1595C>G p.S532* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2
- ZNF750 | c.287_288del p.S96Cfs*125 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by pindel, varscan2
- BEX4 | c.300G>A p.R100= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV101015420; called by muse, mutect2
- C16orf91 | c.258C>T p.L86= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs1005447294, COSV100113787; called by muse, mutect2, varscan2
- CEP78 | c.594G>A p.K198= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99450957; called by muse, mutect2, varscan2
- CNST | c.1452G>C p.L484= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV100830116; called by muse, mutect2, varscan2
- COL4A1 | c.3222C>T p.F1074= | Silent (SNP) | VAF 19/226 reads (8%) | catalogued as COSV101011617; called by muse, mutect2
- COQ7 | c.318C>G p.V106= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100430577, COSV100430594; called by muse, mutect2
- CYP4B1 | c.1101C>G p.T367= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV54721555, COSV99597521; called by muse, mutect2, varscan2
- DCAF6 | c.2433C>T p.L811= (on ENST00000312263 / NM_001349778.1; = p.L831= on NM_018442.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100394894; called by muse, mutect2, varscan2
- DNAH10 | c.5382C>T p.N1794= (on ENST00000409039; = p.N1733= on NM_207437.3) | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs767366047, COSV69000002; called by muse, mutect2
- DRAXIN | c.876C>G p.L292= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs759539187, COSV99610981; called by muse, mutect2, varscan2
- EGFL6 | c.1476G>A p.E492= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV100789961; called by muse, mutect2
- EIF4G3 | c.1449G>A p.E483= | Silent (SNP) | VAF 32/214 reads (15%) | catalogued as COSV99945746; called by muse, mutect2, varscan2
- EPC1 | c.375G>A p.V125= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99553484; called by muse, mutect2, varscan2
- FAM20B | c.324G>A p.L108= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99762653; called by muse, mutect2, varscan2
- GON4L | c.6648T>C p.D2216= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- HECW1 | c.3207G>A p.Q1069= | Silent (SNP) | VAF 7/140 reads (5%) | catalogued as COSV101224352; called by muse, mutect2
- HSPA6 | c.1257C>T p.N419= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100554346; called by muse, mutect2, varscan2
- KSR2 | c.1584G>A p.T528= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs753143776, COSV56676969; called by muse, mutect2, varscan2
- LY6G5C | c.447C>T p.C149= (on ENST00000375863; = p.C74= on NM_025262.3) | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as COSV101020858; called by muse, mutect2, varscan2
- MN1 | c.3021G>A p.S1007= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV56559381; called by muse, mutect2, varscan2
- MPND | c.1275C>T p.L425= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs141733787; called by muse, mutect2, varscan2
- MTCL1 | c.2778G>C p.G926= (on ENST00000306329 / NM_001378206.1; = p.G566= on NM_015210.4) | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV100095634; called by muse, mutect2, varscan2
- OGFOD3 | c.519C>T p.F173= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs1344282798, COSV100234568; called by muse, mutect2, varscan2
- OR14K1 | c.135C>G p.L45= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV99315215, COSV99315503; called by muse, mutect2, varscan2
- OR2G2 | c.840C>T p.F280= | Silent (SNP) | VAF 15/200 reads (8%) | catalogued as COSV100190005, COSV60739800; called by muse, mutect2
- PGRMC1 | c.90C>T p.L30= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV54293314; called by muse, mutect2, varscan2
- SHANK2 | c.4971C>T p.L1657= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs782011985, COSV53621188, COSV99573864; called by muse, mutect2, varscan2
- TEX47 | c.627C>G p.L209= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99787398; called by muse, mutect2, varscan2
- TNK2 | c.819G>A p.L273= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV100361731; called by muse, mutect2, varscan2
- XIRP2 | c.8436G>C p.L2812= (on ENST00000628543; = p.L2987= on NM_152381.6) | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as COSV54709527, COSV99747742; called by muse, mutect2, varscan2
- ZNF423 | c.939C>T p.V313= (on ENST00000563137 / NM_001379286.1; = p.V305= on NM_015069.4) | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs764527468, COSV99283899; called by muse, mutect2, varscan2
- ZNF592 | c.2118C>T p.L706= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as rs1369703286, COSV100246142; called by muse, mutect2
- BTN2A3P | n.1474G>C | RNA (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2
- C16orf91 | c.*190C>G | 3'UTR (SNP) | VAF 32/111 reads (29%) | catalogued as COSV100113786; called by muse, mutect2, varscan2
- MIR124-2 | n.87C>T | RNA (SNP) | VAF 5/45 reads (11%) | catalogued as rs1043697321; called by muse, mutect2, varscan2
- MROH8 | c.109+2729G>C | Intron (SNP) | VAF 35/155 reads (23%) | catalogued as COSV99457978; called by muse, mutect2
